Somatic mutation profile of tumor specimen TARGET-10-PASJLN-09A (aliquot TARGET-10-PASJLN-09A-01D) from TARGET case TARGET-10-PASJLN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,991 days).
Specimen TARGET-10-PASJLN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4338543-a701-49cf-a72c-e7a138e31d09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASJLN-10A (Blood Derived Normal), aliquot TARGET-10-PASJLN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c068af3d-3f84-4b7f-98ee-e2334526e59d

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, 3'UTR 2, Intron 2, Frame Shift Ins 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 73/76 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764327381, COSV51957617; called by muse, mutect2, varscan2
- DENND2A | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318957498, COSV52051078; called by muse, mutect2
- ELL2 | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52980908, COSV52982342; called by muse, mutect2, varscan2
- MYO7B | c.4741A>T p.M1581L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV67347364; called by muse, mutect2, varscan2
- NOTCH1 | c.4355_4356insGGACTTACGAATCT p.E1453Dfs*132 | Frame Shift Ins (INS) | VAF 9/21 reads (43%) | catalogued as COSV53028133, COSV53049513; called by mutect2, pindel*, varscan2*
- PYCR1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201517468, COSV57999672; called by muse, mutect2
- RARRES2 | c.151A>G p.S51G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs940993723, COSV56231201; called by muse, mutect2, varscan2
- SLIT2 | c.1885C>G p.L629V | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56570950; called by muse, mutect2, varscan2
- SYNJ2BP | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56445545; called by muse, mutect2, varscan2
- TLE3 | c.1469G>A p.C490Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58169175; called by muse, mutect2, varscan2
- UNC80 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs536981632, COSV55890576; called by muse, mutect2, varscan2
- ZNF524 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.836); catalogued as rs569740566, COSV55608610; called by mutect2, varscan2
- HMGB1 | c.108_109insTTTTTGGGGGAAGTTC p.N37Ffs*12 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- IRF2BPL | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- COL6A3 | c.5253G>A p.T1751= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as rs886043174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSND | c.*148G>A | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2
- COX10 | c.696-14780T>C | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- GAS8 | c.*1214G>A | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs779304532; called by muse, mutect2, varscan2
- PDGFA | c.580+64G>T | Intron (SNP) | VAF 46/86 reads (53%) | catalogued as rs753138478; called by muse, mutect2, varscan2
